Somatic mutation profile of tumor specimen TCGA-E1-5307-01A (aliquot TCGA-E1-5307-01A-01D-1893-08) from TCGA case TCGA-E1-5307, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 62.5 years (22,837 days).
Specimen TCGA-E1-5307-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64517a79-f926-4a0e-a3b4-7a06ad5a9fd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5307-10A (Blood Derived Normal), aliquot TCGA-E1-5307-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb5de8a0-f2cd-41ac-9c5f-594a2d7bcb0f

The open-access MAF lists 66 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 44, Silent 15, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RASA1 | c.613_617del p.L205Kfs*4 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs1060503441; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 35/44 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC127029.3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs544949394, COSV60111208; called by muse, mutect2, varscan2
- ANAPC2 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV59244982; called by muse, mutect2, varscan2
- ATRX | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 193/372 reads (52%) | catalogued as rs1057523785, COSV64871339; called by muse, mutect2, varscan2
- CCDC102A | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as COSV50777030; called by muse, mutect2
- CCDC93 | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs374241278; called by muse, mutect2, varscan2
- CDK12 | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.057); catalogued as COSV71001201; called by muse, mutect2
- CEP164 | c.3143T>C p.V1048A | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV54042486; called by muse, mutect2, varscan2
- DENND4C | c.5193del p.V1732Ffs*6 (on ENST00000434457 / NM_001330640.2; = p.V1683Ffs*6 on NM_017925.7) | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | catalogued as rs1259424505; called by mutect2, pindel, varscan2
- DPP10 | c.1426A>G p.T476A | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as COSV59694169; called by muse, mutect2, varscan2
- EGF | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554205393, COSV54479134, COSV54480236; called by mutect2, varscan2
- GALR1 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV55317626; called by muse, mutect2, varscan2
- GDPD2 | c.1522A>T p.T508S | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV65533271; called by muse, mutect2, varscan2
- ITPR2 | c.3778C>G p.L1260V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV67270890; called by muse, mutect2, varscan2
- LRIG2 | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63162649; called by muse, mutect2, varscan2
- LRRN2 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65784094; called by muse, mutect2, varscan2
- MS4A8 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs201478139, COSV55754725; called by muse, mutect2, varscan2
- MTUS2 | c.1327A>G p.N443D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV70917380; called by muse, mutect2, varscan2
- OR13G1 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as rs117404602, COSV62944488; called by muse, mutect2, varscan2
- OR5H2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as rs1299420265, COSV62351041; called by muse, mutect2, varscan2
- P2RY2 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as rs1365311850, COSV60776552; called by muse, mutect2
- PCDHGB4 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1015982333, COSV53967938, COSV53971106; called by muse, mutect2, varscan2
- PDHA2 | c.1160T>C p.V387A | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54779812; called by muse, mutect2, varscan2
- PFKL | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57394844; called by muse, varscan2
- PM20D1 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65648376, COSV65649102; called by muse, mutect2, varscan2
- PRF1 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs775966864, COSV64615200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSD3 | c.2942A>G p.Y981C (on ENST00000440756; = p.Y980C on NM_015310.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54073676; called by muse, mutect2, varscan2
- PTGFRN | c.1544G>C p.C515S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753357980, COSV67798830; called by muse, mutect2, varscan2
- RBM12B | c.1612G>C p.D538H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV67898234; called by muse, mutect2, varscan2
- RBM12B | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as COSV67898238; called by muse, mutect2, varscan2
- RBM12B | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV67898242; called by muse, mutect2, varscan2
- RBM12B | c.785G>C p.R262T | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as rs745665846, COSV66968252; called by muse, varscan2
- RBM12B | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.223); catalogued as COSV66968259; called by muse, varscan2
- RBM12B | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV66968261; called by muse, varscan2
- RGMA | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1240213291, COSV61234823; called by muse, mutect2
- RGS3 | c.3392C>T p.A1131V (on ENST00000350696 / NM_001282923.2; = p.A850V on NM_130795.4) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs144334750; called by muse, mutect2, varscan2
- RNF168 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV58838317; called by muse, mutect2, varscan2
- ROR2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65220285; called by muse, mutect2, varscan2
- SLTM | c.1405A>G p.M469V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51054988; called by muse, mutect2
- TCF12 | c.1115-1G>A p.X372_splice | Splice Site (SNP) | VAF 22/51 reads (43%) | catalogued as COSV51009918; called by muse, mutect2, varscan2
- TNXB | c.5794C>G p.P1932A (on ENST00000647633; = p.P1685A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.101); catalogued as COSV100926288; called by muse, mutect2, varscan2
- TRIM32 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs183136193, COSV57787830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP25 | c.2802A>G p.K934= | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as COSV53483785; called by muse, varscan2
- VPS13C | c.3667G>A p.E1223K (on ENST00000644861 / NM_020821.3; = p.E1180K on NM_017684.5) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV51259849; called by muse, mutect2, varscan2
- WARS2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52479366; called by muse, mutect2, varscan2
- ZC3HAV1L | c.779C>G p.T260S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV51964601; called by muse, mutect2, varscan2
- ZNF462 | c.3190C>T p.Q1064* | Nonsense Mutation (SNP) | VAF 12/150 reads (8%) | catalogued as COSV52942743; called by muse, mutect2
- ZNF613 | c.766G>A p.G256R (on ENST00000293471 / NM_001031721.4; = p.G220R on NM_024840.4) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.151); catalogued as COSV53272478; called by muse, mutect2, varscan2
- PBRM1 | c.4127del p.G1376Afs*8 (on ENST00000296302 / NM_001366071.2; = p.G1324Afs*8 on NM_018313.5) | Frame Shift Del (DEL) | VAF 69/179 reads (39%) | called by mutect2, pindel, varscan2
- ABCA7 | c.1164C>T p.D388= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs754600576, COSV54027468; called by muse, mutect2, varscan2
- CDHR3 | c.2277G>A p.T759= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs267601221, COSV58418382; called by muse, mutect2, varscan2
- CNGA3 | c.519C>T p.T173= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as rs763964348, COSV55622286; called by muse, mutect2, varscan2
- DLC1 | c.4269T>G p.P1423= (on ENST00000276297 / NM_001348081.2; = p.P986= on NM_006094.5) | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV52309804; called by muse, mutect2, varscan2
- FAM153B | c.96C>T p.R32= | Silent (SNP) | VAF 7/33 reads (21%) | called by mutect2, varscan2
- IL1B | c.105C>T p.S35= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV54521973; called by muse, mutect2, varscan2
- MTUS1 | c.2394A>C p.G798= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV50562565; called by muse, mutect2, varscan2
- PRR19 | c.162G>T p.V54= | Silent (SNP) | VAF 9/148 reads (6%) | catalogued as COSV56625897; called by muse, mutect2
- RBM12B | c.927G>C p.L309= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV66968250; called by muse, mutect2, varscan2
- SDK1 | c.2052C>T p.H684= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs550278515, COSV101269602, COSV67373879; called by muse, mutect2, varscan2
- SETMAR | c.366C>T p.C122= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV62781001; called by muse, mutect2
- TEF | c.423A>G p.P141= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs1302494289, COSV56748085; called by muse, mutect2, varscan2
- TENM1 | c.1455C>T p.N485= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV64434706; called by muse, mutect2, varscan2
- TMCC1 | c.1185A>G p.E395= (on ENST00000393238 / NM_001349268.2; = p.E71= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs368776883; called by muse, mutect2
- UNC5D | c.117C>T p.G39= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs761905222, COSV54782131; called by muse, mutect2, varscan2
